Gene-level copy-number profile of tumor specimen TCGA-CK-4952-01A from TCGA case TCGA-CK-4952, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.8 years (17,826 days).
Specimen TCGA-CK-4952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d575237b-3173-4183-ae1e-c5533e05fae5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CK-4952-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9760c2af-78f7-4ae8-a523-1f1aaa2f03d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 1,489; copy number 2: 49,356; copy number 3: 5,182; copy number 4: 3,054; copy number 5: 62; copy number 7: 512; copy number 8: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CK-4952-01A-01D-1717-01): tumor purity 0.85, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 625 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:26,748,150–27,210,783, 9 genes, copy number 7 (within-gene range 1–7): ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1.
- chr8:46,922,561–51,321,118, 62 genes, copy number 5 (broad region; genes not listed).
- chr8:108,131,100–116,403,757, 58 genes, copy number 7–8: AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:116,938,207–145,066,685, 496 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,489. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
